Gene-level copy-number profile of tumor specimen TCGA-UF-A7JH-01A from TCGA case TCGA-UF-A7JH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 59.0 years (21,558 days).
Specimen TCGA-UF-A7JH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.c37a5f9c-8f3c-4a39-afc8-812b3fe61105.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UF-A7JH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0684cd4b-a827-46d9-b687-08ffed9bca38

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 1,517; copy number 2: 13,986; copy number 3: 25,986; copy number 4: 15,700; copy number 5: 188; copy number 6: 672; copy number 7: 1,507; copy number 8: 60; copy number 9: 33; copy number 10: 25; copy number 12: 33; copy number 18: 13; copy number 21: 31; copy number 31: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UF-A7JH-01A-21D-A34I-01): tumor purity 0.55, ploidy 3.25, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:177,133,025–177,300,213, 4 genes (within-gene range 0–2): NSD1, AC146507.3, AC146507.2, PRMT1P1.
- chr6:163,956,299–165,077,495, 9 genes (within-gene range 0–2): AL136225.1, Z97205.2, Z97205.1, Z97205.3, AL139190.1, AL358972.1, AL450345.2, AL450345.1, AL133538.1.
- chr17:43,753,738–44,004,469, 14 genes (within-gene range 0–3): SOST, DUSP3, CFAP97D1, AC003098.1, MPP3, CD300LG, MPP2, AC007993.3, FAM215A, AC007993.1, AC007993.2, LINC01976, PPY, PYY.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,730 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:29,748,757–31,558,831, 11 genes, copy number 7: EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501.
- chr7:53,187,388–55,260,256, 31 genes, copy number 8–31: HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr8:56,776,283–145,066,685, 1,366 genes, copy number 7 (broad region; genes not listed).
- chr12:66,767–991,190, 25 genes, copy number 10: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr12:4,097,451–6,451,718, 56 genes, copy number 8: HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1, GALNT8, AC005833.2, KCNA6, AC006063.1, AC006063.3, AC006063.4, AC005906.2, KCNA1, AC006063.2, AC005906.1, KCNA5, AC005906.3, LINC02443, AC006206.2, AC006206.1, AC007848.2, AC007848.1, NTF3, ANO2, AC137627.1, VWF, RN7SL69P, AC005845.1, CD9, Y_RNA, ATP5MFP5, PLEKHG6, TNFRSF1A, RN7SL391P, SCNN1A, LTBR, AC005840.2, AC005840.1, SRP14P1, CD27-AS1, CD27.
- chr12:60,092,864–70,920,738, 210 genes, copy number 7–21 (within-gene range 6–21) (broad region; genes not listed).
- chr12:71,664,301–71,927,248, 9 genes, copy number 7 (within-gene range 2–7): THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr15:94,168,349–94,168,751, 1 gene, copy number 8: H3P40.
- chr21:33,057,829–33,588,706, 21 genes, copy number 9: LINC00945, OLIG1, AP000289.1, AP000290.1, LINC01548, IFNAR2, AP000295.1, IL10RB-DT, IL10RB, IFNAR1, USF1P1, IFNGR2, TMEM50B, RPS5P3, AP000302.1, DNAJC28, GART, BTF3P6, SON, MIR6501, DONSON.

Autosomal genes at a single copy (total copy number 1): 654. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
